Somatic mutation profile of tumor specimen 0DI7V2 from CCDI case PBBTXS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,154 days).
Specimen 0DI7V2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa9af65d-7004-40a9-92e3-c87b9a0fc9fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI7VE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/315567f3-158c-4f35-840f-3c3a7d83641e

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 222/735 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, varscan2
- PTPN11 | c.854T>C p.F285S | Missense Mutation (SNP) | VAF 105/260 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918463, CM021134, CM060447, COSV61005134; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 366/436 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic; called by muse, varscan2
- HOXB2 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.83); PolyPhen benign (0.031); catalogued as rs1049532013; called by muse, varscan2
- PLXNA2 | c.2371A>G p.I791V | Missense Mutation (SNP) | VAF 268/619 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as rs759941477, COSV65437782; called by muse, varscan2
- WIPF3 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 248/326 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs760202840; called by muse, varscan2
- AC242842.3 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 80/584 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.095); called by muse, varscan2
- ATRAID | c.595A>G p.I199V (on ENST00000611786; = p.I86V on NM_016085.5) | Missense Mutation (SNP) | VAF 223/554 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.039); called by muse, varscan2
- ERLIN1 | c.707T>C p.M236T | Missense Mutation (SNP) | VAF 321/741 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.4); called by muse, varscan2
- C19orf53 | c.273C>T p.A91= | Silent (SNP) | VAF 158/330 reads (48%) | catalogued as rs150096940; called by muse, varscan2
- COL11A2 | c.4026C>T p.G1342= (on ENST00000341947 / NM_080680.3; = p.G1235= on NM_080679.2) | Silent (SNP) | VAF 185/512 reads (36%) | catalogued as rs778423110; ClinVar: likely benign; called by muse, varscan2
- SLC38A10 | c.768G>A p.T256= | Silent (SNP) | VAF 164/413 reads (40%) | catalogued as rs781089604; called by muse, varscan2
- SLFN14 | c.837T>C p.P279= | Silent (SNP) | VAF 66/369 reads (18%) | catalogued as rs1236538049; called by muse, varscan2
- EVPL | c.2661+33T>C | Intron (SNP) | VAF 90/239 reads (38%) | catalogued as rs1220354762; called by muse, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, varscan2
